CCDI case PBCENC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx.
https://portal.gdc.cancer.gov/cases/20ac7fad-9753-452c-a429-761d127fd069

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Mucosa of lip, NOS; Age at diagnosis: 1.2 years (456 days).

Biospecimens (3 samples)
- Sample 0DQ55G: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ55N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ55W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
